Somatic mutation profile of tumor specimen 0DSR4Y from CCDI case PBCGSX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.7 years (5,374 days).
Specimen 0DSR4Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25ef956a-597d-4538-b0e4-f70b2a8ed9ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSR58 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83f2ab92-425c-4464-858b-537113932f77

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, IGR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 287/816 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DCX | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 128/322 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs587783568, CM023363, CM087666; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NAF1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 234/693 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1260753515; called by muse, mutect2, varscan2
- CAPN15 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, varscan2
- LPA | c.5798C>A p.T1933N | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC25A17 | c.291A>T p.Q97H | Missense Mutation (SNP) | VAF 181/346 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PNPO | c.138+43A>G | Intron (SNP) | VAF 3/24 reads (13%) | catalogued as rs1285377605; called by muse, varscan2
- Unknown | chr11:122200820 C>T | IGR (SNP) | VAF 4/32 reads (13%) | catalogued as rs184016870; called by mutect2, varscan2
- YJU2 | chr19:4247060 G>C | 5'Flank (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2
